Gene-level copy-number profile of tumor specimen TCGA-12-0778-01A from TCGA case TCGA-12-0778, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.3 years (19,460 days).
Specimen TCGA-12-0778-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.c1750417-983e-4222-a281-18d5b38537f2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-0778-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6939287-dc28-44cf-a8bc-58f7016fb5f9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 78; copy number 1: 6,252; copy number 2: 36,669; copy number 3: 16,402; copy number 4: 410; copy number 26: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-0778-01A-01D-0333-01): tumor purity 0.63, ploidy 2.21, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 78 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,507,452–23,438,700, 78 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,933,699–55,211,628, 3 genes, copy number 26: AC006971.1, EGFR, EGFR-AS1.

Autosomal genes at a single copy (total copy number 1): 3,872. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
